Surgical pathology report (de-identified scan), TCGA case TCGA-31-1956, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1956-01A (Primary Tumor).

[page 1 of 2]
Consent: [REDACTED]

Specimen Type:

- 1: Omentum
- 2: LT OVARY
- 3: PERITONEAL DEPOSIT

Clinical Details:

Ovarian Tumour

[REDACTED] TCGA-31-1956

Macroscopic Description:

1) Omentum

This is a piece of omental fat measuring 12.5 x 6 x 1.5cm, with multiple solid firm areas.

BLOCK A to C – 1pc each, [REDACTED]

2) Left Ovary

This is an irregular soft firm specimen weighing 30grams and measures 5 x 4.5 x 3cm, with few membranous fragments adherent to it.

BLOCK A to D – 1pc each, representative slices. [REDACTED]

3) Biopsy from Peritoneal Surface of abdominal wall.

This is a soft firm irregular piece of tan to brown tissue, measuring 2 x 1.3 x 0.5cm. Bisected.

BLOCK: 1, 2pcs. [REDACTED]

Microscopic Description:

CASE SHOWN AT [REDACTED] MEETING [REDACTED]

All three specimens contain similar adenocarcinoma, which is all viable, poorly differentiated and has a predominant solid sheet-like pattern.

In the ovary, there are slit-like spaces and some bizarre giant cells indicating serous differentiation. The tumour is extracapsular, and present within the adherent ovarian ligaments.

In the omentum, the tumour is destructive, with the largest single area (formed of contiguous modules of tumour) being 16 millimetres across, but nowhere quite reaching a single solid mass greater than two centimetres across. Lymphatic but no vascular invasion is present here.

[page 2 of 2]
In the nodule from the peritoneal surface of the abdominal wall, the tumour is all viable and measures 11 millimetres across, surrounded by fibrotic tissue within which no definite muscle is identifiable.

TCGA-31-1956

Final Diagnosis:

1. OMENTUM: METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA, FIGO GRADE 3, STAGE 3B, VIABLE
2. LT OVARY: POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA REACHING CAPSULE AND INTO OVARIAN LIGAMENT
3. PERITONEAL DEPOSIT: POORLY DIFFERENTIATED VIABLE METASTATIC ADENOCARCINOMA 11 MM ACROSS

Additional Pathologist(s)/BMS(s)

Source: NCI Genomic Data Commons file c7949f7d-ccf9-4040-9ba2-09d879b033d7 (TCGA-31-1956.3646C24B-C4B7-400B-BC93-7EF485C6892C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).